Somatic mutation profile of tumor specimen MP2PRT-PARBVY-TBP1-A (aliquot MP2PRT-PARBVY-TBP1-A-1-0-D-A83N-36) from MP2PRT case MP2PRT-PARBVY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.7 years (2,447 days).
Specimen MP2PRT-PARBVY-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 29124243-7a59-4c78-9e11-73cac05cb8d8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARBVY-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARBVY-NB1-A-1-0-D-A83N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4eaadb33-63c3-43d2-a8c9-5b3facf747f2

The open-access MAF lists 27 somatic variants for this specimen: 19 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 6, Frame Shift Ins 1, 3'UTR 1, Intron 1, Frame Shift Del 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2503G>T p.D835Y | Missense Mutation (SNP) | VAF 61/265 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913488, COSV54042116, COSV54042636, COSV54045151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARHGAP39 | c.1151G>A p.S384N | Missense Mutation (SNP) | VAF 99/469 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.478); catalogued as rs1036735693; called by muse, mutect2, varscan2
- C4orf54 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 54/524 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.96); catalogued as rs776459396; called by muse, mutect2
- COL6A1 | c.424G>A p.V142M | Missense Mutation (SNP) | VAF 28/368 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as rs144282452; called by muse, mutect2
- CTCF | c.1015C>T p.R339W | Missense Mutation (SNP) | VAF 13/385 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1243010179, COSV50486171; called by muse, mutect2
- FAM221B | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 28/336 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.809); catalogued as rs943024291, COSV65074389; called by muse, mutect2
- GRM3 | c.2011G>A p.D671N | Missense Mutation (SNP) | VAF 64/204 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs138880384; called by muse, mutect2, varscan2
- MXI1 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 104/355 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1438632540; called by muse, mutect2, varscan2
- ORC5 | c.1250G>A p.R417K | Missense Mutation (SNP) | VAF 23/234 reads (10%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.525); catalogued as COSV52402617; called by muse, mutect2
- ZFP42 | c.791C>T p.T264M | Missense Mutation (SNP) | VAF 110/404 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1052462774, COSV58817514; called by muse, mutect2, varscan2
- EZH2 | c.1975G>A p.D659N (on ENST00000460911 / NM_001203247.2; = p.D664N on NM_004456.5) | Missense Mutation (SNP) | VAF 72/168 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGHV3-7 | chr14:106062142 CACTGTGTCTCTCGCACAGTAATACACG>GAGA | Missense Mutation (DEL) | VAF 64/190 reads (34%) | called by pindel, varscan2*
- IGHV4-59 | c.350delinsCCCCCC | In Frame Ins (INS) | VAF 99/261 reads (38%) | called by mutect2*, pindel, varscan2*
- KCNE2 | c.316T>A p.S106T | Missense Mutation (SNP) | VAF 69/490 reads (14%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- MARCHF10 | c.1001A>G p.E334G | Missense Mutation (SNP) | VAF 42/250 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NELFE | c.323_324insTTTTTTC p.Q108Hfs*12 | Frame Shift Ins (INS) | VAF 39/273 reads (14%) | called by mutect2, pindel*, varscan2
- PDE4A | c.2516T>C p.L839P (on ENST00000380702 / NM_001111307.2; = p.L600P on NM_006202.3) | Missense Mutation (SNP) | VAF 174/370 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SYNGR2 | c.284T>A p.I95N | Missense Mutation (SNP) | VAF 43/234 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- TRAJ29 | c.5_8del p.N2Kfs*16 | Frame Shift Del (DEL) | VAF 31/110 reads (28%) | called by pindel*, varscan2
- COL19A1 | c.1758G>T p.L586= | Silent (SNP) | VAF 76/191 reads (40%) | catalogued as rs1299053621; called by muse, mutect2, varscan2
- PCDHAC2 | c.1071C>T p.D357= | Silent (SNP) | VAF 81/284 reads (29%) | catalogued as COSV53858567; called by muse, mutect2, varscan2
- RBM24 | c.408C>T p.H136= (on ENST00000379052 / NM_001143942.2; = p.H91= on NM_153020.2) | Silent (SNP) | VAF 50/205 reads (24%) | catalogued as rs201520159; called by muse, mutect2, varscan2
- SNCAIP | c.438C>T p.Y146= | Silent (SNP) | VAF 131/274 reads (48%) | catalogued as rs150946460, COSV54405314; ClinVar: likely benign; called by muse, mutect2, varscan2
- TNN | c.2061C>T p.H687= | Silent (SNP) | VAF 59/216 reads (27%) | catalogued as rs370669454, COSV53422792; called by muse, varscan2
- USP17L1 | c.1254C>T p.P418= | Silent (SNP) | VAF 48/606 reads (8%) | catalogued as rs560367431; called by muse, mutect2
- ARHGAP19 | c.57-4508T>A | Intron (SNP) | VAF 32/292 reads (11%) | called by muse, mutect2, varscan2
- INTS8 | c.*629A>C | 3'UTR (SNP) | VAF 23/363 reads (6%) | called by muse, mutect2
